CCDI case PBCMJN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/9fc31cdb-f866-40d2-92ad-b7c3356ece19

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 14.9 years (5,436 days).

Biospecimens (2 samples)
- Sample 0DVZEA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZEH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
